Somatic mutation profile of tumor specimen TCGA-EJ-5530-01A (aliquot TCGA-EJ-5530-01A-01D-1576-08) from TCGA case TCGA-EJ-5530, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.1 years (22,316 days).
Specimen TCGA-EJ-5530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b43913-fd91-4111-b684-1de05ef147d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5530-10A (Blood Derived Normal), aliquot TCGA-EJ-5530-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cfb0a25-f9ff-4f0a-bcf6-901cac199cca

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 3, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs782356392, COSV53990957; called by muse, mutect2, varscan2
- AIFM3 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV58999748; called by muse, mutect2
- AKR1A1 | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61086843, COSV61087309; called by muse, mutect2
- ALDH1A3 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV60901806; called by muse, mutect2, varscan2
- ARHGAP21 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369698657; called by muse, mutect2
- CDH18 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV56924842; called by muse, mutect2
- CNOT3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 21/311 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55360792; called by muse, mutect2
- CNTNAP5 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV101443851, COSV70486688; called by muse, mutect2, varscan2
- DCAF4L2 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs779852288, COSV60479001; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2
- ETV3 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58748086; called by muse, mutect2
- FNDC3A | c.3136G>T p.V1046F (on ENST00000492622 / NM_001079673.2; = p.V990F on NM_014923.5) | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs1403684947, COSV68133337; called by muse, mutect2
- IL17RC | c.1075T>A p.C359S (on ENST00000295981 / NM_153461.4; = p.C273S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55973401; called by muse, mutect2
- KIAA0895 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV51710981; called by muse, mutect2
- KSR1 | c.1580C>T p.P527L (on ENST00000644974 / NM_001367810.1; = p.P412L on NM_014238.2) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs754753981, COSV52033172; called by muse, mutect2, varscan2
- LHX3 | c.742G>A p.G248R (on ENST00000371748 / NM_178138.6; = p.G253R on NM_014564.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs1000049571, COSV65581933; called by mutect2, varscan2
- MB21D2 | c.258C>A p.Y86* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as rs1281530023, COSV66663670; called by muse, mutect2, varscan2
- MORC1 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV51720769; called by muse, mutect2
- MUC16 | c.17047G>A p.V5683I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs370295620, COSV67468811; called by muse, mutect2
- NBEAL1 | c.6299C>G p.S2100* | Nonsense Mutation (SNP) | VAF 8/198 reads (4%) | catalogued as COSV68916107; called by muse, mutect2
- NKX3-1 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101082841, COSV66512113; called by muse, mutect2
- NUBPL | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs760587173, COSV55268955; called by muse, mutect2, varscan2
- OR5AS1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs775842242, COSV57981863, COSV57983631; called by muse, mutect2
- PACSIN2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs1321548299, COSV54317960; called by muse, mutect2, varscan2
- PCDHGA10 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); catalogued as COSV53955498; called by muse, mutect2, varscan2
- RBFOX1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV60960023; called by muse, mutect2
- RPL8 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); catalogued as COSV52799294; called by muse, mutect2
- RTP5 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as rs931131969, COSV58320219; called by muse, mutect2
- SEC23B | c.687C>T p.S229= | Splice Region (SNP) | VAF 4/60 reads (7%) | catalogued as COSV52720711; called by muse, mutect2
- TTN | c.6358C>T p.R2120W (on ENST00000591111; = p.R2074W on NM_003319.4) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | PolyPhen probably damaging (0.96); catalogued as rs116158152, COSV59904099; ClinVar: uncertain significance; called by muse, mutect2
- WDR64 | c.2657C>G p.S886C | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63796286; called by muse, mutect2
- ZNF43 | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV61684116; called by muse, mutect2
- ARHGEF40 | c.2730G>A p.R910= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100070735; called by muse, varscan2
- CACNA1E | c.4347C>T p.F1449= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs368943151; called by muse, mutect2, varscan2
- CALB2 | c.648C>T p.D216= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs770985522, COSV56939625; called by muse, mutect2, varscan2
- CCDC105 | c.1095G>A p.T365= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV52963179; called by muse, mutect2, varscan2
- GPR157 | c.480C>T p.D160= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1216971340, COSV66233680; called by muse, mutect2, varscan2
- NUTM1 | c.3354C>T p.D1118= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as COSV59217028; called by muse, mutect2, varscan2
- PCDHA11 | c.2211G>A p.T737= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs199741530, COSV56505320; called by muse, mutect2
- RPS6KA6 | c.156T>A p.V52= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV53120228; called by muse, mutect2
- SAP30BP | c.22C>T p.L8= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1029021417, COSV53126791; called by muse, mutect2
- SPEG | c.2956C>T p.L986= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100405743; called by muse, mutect2
- TNXB | c.9501C>T p.R3167= (on ENST00000647633; = p.R2920= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs747920918, COSV64479648; called by muse, mutect2, varscan2
- DUSP13 | c.*832G>A | 3'UTR (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57814631; called by muse, mutect2, varscan2
- FGFR3 | c.*1044C>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs1195256125; called by muse, mutect2
